Gene-level copy-number profile of tumor specimen TCGA-BR-6456-01A from TCGA case TCGA-BR-6456, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.7 years (27,288 days).
Specimen TCGA-BR-6456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.005dbb8a-a03e-4f93-ab1f-17ea2e47aabf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-6456-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/115ccafe-6610-454e-9372-b994dbed5406

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 12,421; copy number 2: 30,403; copy number 3: 9,956; copy number 4: 6,784; copy number 5: 140; copy number 6: 79; copy number 7: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-6456-01A-11D-1799-01): tumor purity 0.3, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:30,292,548–30,894,765, 9 genes: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 221 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:85,061,213–85,649,283, 34 genes, copy number 5: LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68.
- chr5:149,141,483–149,634,968, 19 genes, copy number 5: ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145, CSNK1A1, AC021078.1, RPL29P14, ARHGEF37, RNU6-588P.
- chr6:106,358,566–107,051,586, 16 genes, copy number 5: AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1.
- chr7:16,461,481–16,530,580, 1 gene, copy number 5 (within-gene range 4–5): SOSTDC1.
- chr7:16,526,825–16,888,885, 13 genes, copy number 5: LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:16,938,225–16,938,557, 1 gene, copy number 5: AC098592.1.
- chr7:17,033,089–17,033,478, 1 gene, copy number 5: BRWD1P3.
- chr8:95,206,876–95,269,201, 2 genes, copy number 7: LINC01298, C8orf37.
- chr10:18,545,561–20,289,856, 20 genes, copy number 5 (within-gene range 3–5): NSUN6, ARL5B, AL512641.1, AIFM1P1, AL357520.1, MALRD1, UBE2V2P1, AL590378.1, HMGN1P20, AL354695.1, U3, RNA5SP303, AL157895.1, MTND1P37, MTND2P16, RNU6-1212P, AL353147.1, PLXDC2, AC069549.1, AC069549.2.
- chr10:122,910,610–124,450,048, 25 genes, copy number 5: FAM24A, C10orf88, PSTK, IKZF5, ACADSB, HMX3, HMX2, BUB3, RPS26P39, AL160290.2, LINC02641, AL160290.1, AL357127.2, AL357127.1, GPR26, CPXM2, AC009987.1, AC068058.1, BX469938.1, YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1.
- chr10:124,489,823–124,490,578, 1 gene, copy number 5: RPS10P18.
- chr13:26,557,683–27,182,998, 13 genes, copy number 6 (within-gene range 4–6): WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2.
- chr20:958,452–1,817,765, 33 genes, copy number 6 (within-gene range 2–6): RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1, SIRPB3P, RN7SL561P, AL109809.3, AL109809.2, AL109809.4, CKAP2LP1, AL109809.1.
- chr20:49,237,946–50,192,668, 33 genes, copy number 6 (within-gene range 4–6): ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB.
- chr21:41,361,999–41,697,336, 9 genes, copy number 5 (within-gene range 4–5): MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111.

Autosomal genes at a single copy (total copy number 1): 12,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
